Somatic mutation profile of tumor specimen TCGA-58-A46J-01A (aliquot TCGA-58-A46J-01A-11D-A24D-08) from TCGA case TCGA-58-A46J, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.8 years (23,653 days).
Specimen TCGA-58-A46J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d04500e-bb2e-415f-a95b-d1ceae3f5a76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-A46J-10A (Blood Derived Normal), aliquot TCGA-58-A46J-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ce94d9a-0895-4392-97c1-46995f5a4689

The open-access MAF lists 182 somatic variants for this specimen: 140 protein-altering or splice-affecting, 38 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 38, Nonsense Mutation 10, Frame Shift Del 8, Splice Region 3, RNA 3, Splice Site 2, Frame Shift Ins 2, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs758892087, COSV100717447, COSV100717452; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SERPING1 | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 9/101 reads (9%) | catalogued as rs1554995860, CM133510, COSV99558054; ClinVar: pathogenic; called by muse, mutect2
- ABCC8 | c.801del p.C267Wfs*92 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | catalogued as CM092536, COSV100216993; called by mutect2, pindel, varscan2
- ACAP2 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV100462467; called by muse, mutect2, varscan2
- ALPK3 | c.2732C>T p.T911I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV51932871; called by muse, mutect2, varscan2
- ANK1 | c.1352A>T p.E451V | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV99225986; called by muse, mutect2, varscan2
- ARHGAP15 | c.793C>A p.L265M | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as COSV54479399, COSV99712075; called by muse, mutect2
- ASXL3 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV52457506, COSV52469555; called by muse, mutect2, varscan2
- B3GAT1 | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100438081; called by muse, mutect2
- BCHE | c.1229C>G p.P410R | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs1412780129, COSV100011914, COSV100012805; called by muse, mutect2, varscan2
- BMX | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as COSV100564259, COSV100564556; called by muse, mutect2
- BPTF | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV100075392; called by muse, mutect2, varscan2
- BTK | c.1861C>A p.L621M | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV100437716; called by muse, mutect2, varscan2
- C3AR1 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs780278001, COSV99368756; called by muse, mutect2, varscan2
- C4BPB | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99700061; called by muse, mutect2, varscan2
- C5orf34 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.152); catalogued as COSV100175525; called by muse, mutect2
- CCRL2 | c.924C>A p.S308R | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100645062; called by muse, mutect2, varscan2
- CDC40 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV100309456; called by muse, mutect2, varscan2
- CDCA2 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 19/141 reads (13%) | catalogued as COSV99648715; called by muse, mutect2, varscan2
- CDKN1A | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV55186863; called by muse, varscan2
- CHD3 | c.1421G>T p.C474F | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100391389; called by muse, mutect2, varscan2
- CHD3 | c.1422C>G p.C474W | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100391391; called by muse, mutect2, varscan2
- COPA | c.1221G>T p.A407= | Splice Region (SNP) | VAF 16/98 reads (16%) | catalogued as rs748206343, COSV99616225; called by muse, mutect2, varscan2
- CSMD3 | c.10827G>T p.L3609= (on ENST00000297405 / NM_001363185.1; = p.L3440= on NM_052900.3) | Splice Region (SNP) | VAF 12/125 reads (10%) | catalogued as COSV52174855, COSV99840019; called by muse, mutect2, varscan2
- DCSTAMP | c.720G>T p.W240C | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99886732; called by muse, mutect2
- DNAAF4 | c.684T>A p.S228R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100336840; called by muse, mutect2, varscan2
- DNAH5 | c.3743A>G p.K1248R | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV99451709; called by muse, mutect2, varscan2
- EGFL6 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100789909; called by muse, mutect2, varscan2
- EPB41L2 | c.2336A>T p.E779V | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.691); catalogued as COSV100441074; called by muse, mutect2, varscan2
- EPHA5 | c.1447A>C p.N483H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV56640847, COSV99899988; called by muse, mutect2, varscan2
- ERMN | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV101263055; called by muse, mutect2, varscan2
- ESR1 | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99240020; called by muse, mutect2
- ESYT1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV99920097; called by muse, mutect2, varscan2
- FAT4 | c.5921-1G>T p.X1974_splice | Splice Site (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100629311; called by muse, mutect2
- FBXL3 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV100842378; called by muse, mutect2, varscan2
- FNDC3A | c.2612A>G p.H871R (on ENST00000492622 / NM_001079673.2; = p.H815R on NM_014923.5) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV101256863; called by muse, mutect2, varscan2
- GALNT11 | c.1520T>C p.V507A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100231933; called by muse, mutect2, varscan2
- GALNT14 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.034); catalogued as COSV61110524; called by muse, mutect2, varscan2
- GARRE1 | c.972G>T p.Q324H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100209066, COSV100209578; called by muse, mutect2, varscan2
- GJA8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99569549; called by muse, mutect2, varscan2
- GLRA2 | c.829T>C p.W277R | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99491349; called by muse, mutect2, varscan2
- GRIN2B | c.3632G>T p.G1211V | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as COSV101663116; called by muse, mutect2, varscan2
- HCN1 | c.2044A>G p.S682G | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.039); catalogued as COSV57500446; called by muse, mutect2
- HMGCLL1 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99232684; called by muse, mutect2, varscan2
- HNF4G | c.818A>T p.Y273F (on ENST00000354370 / NM_001330561.2; = p.Y320F on NM_004133.5) | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100584770, COSV62967083; called by muse, mutect2, varscan2
- IFNW1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 16/121 reads (13%) | catalogued as COSV101207631; called by muse, mutect2, varscan2
- IGSF21 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99245566; called by muse, mutect2
- KATNAL2 | c.1552A>T p.K518* (on ENST00000356157 / NM_001353899.1; = p.K446* on NM_031303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99797196; called by muse, mutect2, varscan2
- KCND2 | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV100477158; called by muse, mutect2, varscan2
- KCNQ5 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100572475, COSV59648018; called by muse, mutect2, varscan2
- KCNT2 | c.1714A>T p.S572C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV99655182; called by muse, mutect2, varscan2
- MAGI3 | c.2085C>G p.I695M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100289708; called by muse, mutect2, varscan2
- MAST2 | c.4931C>G p.S1644C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as rs376486053; called by muse, mutect2, varscan2
- MTMR3 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100071077; called by muse, mutect2, varscan2
- MTUS1 | c.2928G>C p.E976D (on ENST00000262102 / NM_001363061.1; = p.E142D on NM_020749.4) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs756490751, COSV99870354; called by muse, mutect2, varscan2
- NDST4 | c.953C>A p.T318K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99997076; called by mutect2, varscan2
- NEXMIF | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99281256; called by muse, mutect2, varscan2
- NKX2-2 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101010602; called by muse, mutect2
- NOL4 | c.1869A>T p.L623F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99307452; called by muse, mutect2, varscan2
- OPCML | c.793A>T p.T265S | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100103158; called by muse, mutect2
- OR2AK2 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100824076; called by muse, mutect2, varscan2
- OR2T4 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100822544; called by muse, mutect2, varscan2
- OR4K15 | c.128G>T p.S43I (on ENST00000305051; = p.S19I on NM_001005486.1) | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100521105; called by muse, mutect2, varscan2
- OR52A1 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100200530, COSV61093128; called by muse, mutect2, varscan2
- OR52E4 | c.573T>A p.C191* | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as COSV100389304; called by muse, mutect2, varscan2
- OR56A1 | c.124A>T p.M42L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1435491268, COSV100360512; called by muse, mutect2
- OR5AR1 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265709; called by muse, mutect2
- OR5AR1 | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100265711; called by muse, mutect2
- PASK | c.3512C>T p.P1171L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377512534; called by muse, mutect2, varscan2
- PCDH15 | c.4958C>A p.T1653K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.02); catalogued as COSV64670190; called by muse, mutect2, varscan2
- PCLO | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100434619; called by muse, mutect2, varscan2
- PDZRN3 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs1365371615, COSV99730816; called by muse, mutect2, varscan2
- PHEX | c.759G>T p.M253I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV101039823; called by muse, mutect2, varscan2
- PHEX | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV101039824; called by muse, mutect2, varscan2
- PLA2G15 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99547279; called by muse, mutect2
- PLCB1 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as COSV100571635; called by muse, mutect2, varscan2
- PLCH1 | c.542G>C p.R181T (on ENST00000340059 / NM_001130960.2; = p.R193T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100397502, COSV58210074; called by muse, mutect2, varscan2
- PPP1R15B | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100916355; called by muse, mutect2, varscan2
- PPP1R3D | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62564270; called by muse, mutect2, varscan2
- PREP | c.837G>T p.R279S (on ENST00000369110; = p.R345S on NM_002726.5) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100964085; called by muse, mutect2, varscan2
- PRLR | c.1123T>C p.Y375H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99184555; called by muse, mutect2, varscan2
- PTGFR | c.263C>A p.A88E | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100882331; called by muse, mutect2, varscan2
- PTPRD | c.4028C>T p.A1343V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs868210901, COSV100645631; called by muse, mutect2, varscan2
- PTPRR | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV51728481, COSV99318111; called by muse, mutect2, varscan2
- PTPRS | c.4467G>T p.M1489I | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53638329, COSV99511465; called by muse, mutect2
- PUS1 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as COSV100435255; called by muse, mutect2
- RANBP2 | c.7988G>T p.R2663I | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV51696734, COSV51709540; called by muse, mutect2, varscan2
- RASA1 | c.3060G>C p.Q1020H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV56925082; called by muse, mutect2, varscan2
- RNASE10 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs772819067, COSV100116183; called by muse, mutect2, varscan2
- RO60 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100814411; called by muse, mutect2, varscan2
- RPS6KA4 | c.1489A>T p.K497* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99590238; called by muse, mutect2, varscan2
- RTL10 | c.262A>G p.S88G | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201726697, COSV100144255; called by muse, mutect2, varscan2
- SCGN | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs752991115, COSV58546319; called by muse, mutect2, varscan2
- SCN2B | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.191); catalogued as COSV99635845; called by muse, mutect2, varscan2
- SDK1 | c.5969G>A p.S1990N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101269600; called by muse, mutect2, varscan2
- SDR16C5 | c.708A>T p.T236= | Splice Region (SNP) | VAF 11/82 reads (13%) | catalogued as COSV58126493; called by muse, mutect2, varscan2
- SEMA4F | c.1688del p.P563Lfs*9 | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | catalogued as COSV60285759; called by mutect2, pindel, varscan2
- SHCBP1 | c.690-2A>T p.X230_splice | Splice Site (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100317430; called by muse, mutect2, varscan2
- SIGLEC12 | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs947088142, COSV99077713; called by muse, mutect2
- SIPA1L3 | c.1877G>A p.G626D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99729520; called by muse, mutect2
- SLC26A6 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100258547, COSV100258854; called by muse, mutect2, varscan2
- SLC35G5 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.71); catalogued as COSV99644416; called by muse, varscan2
- SLC39A10 | c.1681C>A p.L561I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100660677; called by muse, mutect2, varscan2
- SOX2 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV100327250; called by muse, mutect2, varscan2
- SRSF7 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.845); catalogued as COSV100492715; called by muse, mutect2, varscan2
- STRC | c.3763G>A p.G1255R | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as rs558661086, COSV101372227; called by mutect2, varscan2
- SYNE1 | c.18512G>T p.R6171M (on ENST00000367255 / NM_182961.4; = p.R6100M on NM_033071.3) | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99571707; called by muse, mutect2, varscan2
- SYNE1 | c.5161G>A p.E1721K (on ENST00000367255 / NM_182961.4; = p.E1728K on NM_033071.3) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV54960513; called by muse, mutect2, varscan2
- TDRD1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV99314805; called by muse, mutect2, varscan2
- TET2 | c.2650C>T p.Q884* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV54405122, COSV99483674; called by muse, mutect2, varscan2
- TEX15 | c.794C>A p.T265N (on ENST00000256246; = p.T648N on NM_001350162.2) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as rs868204935, COSV99821745; called by muse, mutect2, varscan2
- THADA | c.3143T>C p.M1048T | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100369083; called by muse, mutect2, varscan2
- TMEM132B | c.3062G>A p.R1021K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV54748482; called by muse, mutect2, varscan2
- TMPRSS15 | c.2167A>T p.S723C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV99518515, COSV99519848; called by muse, mutect2, varscan2
- TRAV12-2 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs757668504; called by muse, mutect2, varscan2
- TRHDE | c.2383C>A p.P795T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.111); catalogued as COSV99669478; called by muse, mutect2, varscan2
- TRIM22 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV101181417; called by muse, mutect2, varscan2
- TTN | c.55071G>C p.W18357C (on ENST00000591111; = p.W10933C on NM_003319.4) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV100620717, COSV59966972; called by muse, mutect2, varscan2
- USH2A | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100238456; called by muse, mutect2, varscan2
- WDR64 | c.2642T>C p.V881A | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.582); catalogued as rs559749589, COSV100843891; called by muse, mutect2, varscan2
- ZBTB11 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100465617, COSV57246766; called by muse, mutect2, varscan2
- ZDHHC14 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100399330; called by muse, mutect2, varscan2
- ZEB2 | c.3108T>A p.F1036L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100356455; called by muse, mutect2, varscan2
- ZNF208 | c.2261G>C p.C754S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101237133; called by muse, mutect2, varscan2
- ZNF267 | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV100339853; called by muse, mutect2, varscan2
- ZNF521 | c.1819C>A p.L607I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.183); catalogued as COSV100832765; called by muse, mutect2, varscan2
- ZNF611 | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs767922270, COSV100160452; called by muse, mutect2, varscan2
- ZNF7 | c.1205C>A p.A402E | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100295999, COSV100296164; called by muse, mutect2, varscan2
- ARID1A | c.2549dup p.Y850* | Nonsense Mutation (INS) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- GDF10 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HEATR9 | c.1598C>A p.T533K | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDF1 | c.22del p.R8Afs*240 | Frame Shift Del (DEL) | VAF 24/89 reads (27%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.943G>T p.G315W | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NF1 | c.6462_6490del p.E2155Vfs*4 (on ENST00000358273 / NM_001042492.3; = p.E2134Vfs*4 on NM_000267.3) | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- NFE2L1 | c.706dup p.E236Gfs*9 | Frame Shift Ins (INS) | VAF 30/115 reads (26%) | called by mutect2, pindel, varscan2
- NKAIN3 | c.159del p.T54Pfs*9 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- PLCH1 | c.2783del p.G928Afs*15 (on ENST00000340059 / NM_001130960.2; = p.G920Afs*15 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- RYR2 | c.2129del p.G710Afs*32 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel, varscan2
- TRIM56 | c.1490del p.F497Sfs*35 | Frame Shift Del (DEL) | VAF 15/126 reads (12%) | called by mutect2, varscan2
- TSKS | c.1346dup p.C449Wfs*119 | Frame Shift Ins (INS) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- ABCC3 | c.2259G>A p.G753= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99559452; called by muse, mutect2, varscan2
- ACAP2 | c.1896G>C p.V632= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV100462469; called by muse, mutect2, varscan2
- CDH17 | c.408G>A p.R136= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs1485859532, COSV99217705; called by muse, mutect2, varscan2
- CFHR2 | c.390A>T p.V130= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100804361; called by muse, mutect2, varscan2
- CHRNB2 | c.942C>T p.T314= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100872632; called by muse, mutect2
- COL9A3 | c.1482C>T p.P494= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs1403348219, COSV58985792; called by muse, mutect2, varscan2
- DBX2 | c.1017C>A p.V339= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100224392; called by muse, mutect2, varscan2
- DIO3 | c.516G>T p.P172= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100832165; called by muse, mutect2, varscan2
- E2F7 | c.645G>T p.L215= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100523673; called by muse, mutect2, varscan2
- GBP6 | c.843C>T p.L281= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100969599; called by muse, mutect2, varscan2
- GDF7 | c.490C>A p.R164= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99694153; called by muse, mutect2
- GIP | c.159G>A p.A53= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs267604934, COSV62467429; called by muse, mutect2, varscan2
- GRM8 | c.2328T>C p.T776= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100284430; called by muse, mutect2, varscan2
- HEPACAM2 | c.447A>C p.P149= (on ENST00000394468 / NM_001039372.4; = p.P137= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100506652; called by muse, mutect2, varscan2
- IKBKB | c.1299C>G p.V433= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV60598456; called by muse, mutect2
- IRGC | c.861C>G p.A287= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV99746420; called by muse, mutect2, varscan2
- ISM2 | c.676C>T p.L226= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs757401993, COSV99376746; called by muse, mutect2, varscan2
- KIAA0753 | c.2430A>G p.E810= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV63817951; called by muse, mutect2, varscan2
- LRP2 | c.10032A>C p.A3344= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99789434; called by muse, mutect2, varscan2
- MYO5B | c.3729G>T p.L1243= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV99545715; called by muse, mutect2, varscan2
- NOS3 | c.765G>T p.R255= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99871895; called by muse, varscan2
- OR2A7 | c.21C>T p.S7= | Silent (SNP) | VAF 15/350 reads (4%) | catalogued as COSV101512228; called by muse, mutect2
- OR4N2 | c.39C>A p.I13= | Silent (SNP) | VAF 33/434 reads (8%) | catalogued as COSV100269787; called by muse, mutect2
- PIWIL4 | c.675C>T p.N225= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as COSV100133309; called by muse, mutect2, varscan2
- PNMA8B | c.255G>A p.K85= | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as COSV100885470; called by muse, mutect2, varscan2
- PRKCZ | c.1113G>T p.G371= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV101057928; called by muse, mutect2, varscan2
- PTPRE | c.1215C>T p.S405= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1309049344, COSV99617597, COSV99618393; called by muse, mutect2, varscan2
- REG1A | c.96C>A p.A32= | Silent (SNP) | VAF 41/266 reads (15%) | catalogued as COSV52069944; called by muse, mutect2, varscan2
- SIGLEC12 | c.147C>A p.P49= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs957729266, COSV99389469; called by muse, mutect2
- SLITRK3 | c.2880T>A p.L960= | Silent (SNP) | VAF 34/233 reads (15%) | catalogued as COSV53851784, COSV99579620; called by muse, mutect2, varscan2
- SMCHD1 | c.723A>G p.Q241= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99862021; called by muse, mutect2, varscan2
- SYT14 | c.234C>T p.S78= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV55061757; called by muse, mutect2
- UBTF | c.816C>T p.I272= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs567808617, COSV100256025; called by muse, mutect2, varscan2
- UBTF | c.645C>G p.L215= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as COSV100256027; called by muse, mutect2, varscan2
- UMPS | c.957A>G p.G319= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99229176; called by muse, mutect2
- USP30 | c.838C>A p.R280= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as COSV99980474; called by muse, mutect2, varscan2
- ZBBX | c.2202G>T p.L734= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100284480; called by muse, mutect2, varscan2
- ZNF10 | c.459C>A p.T153= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99940080; called by muse, mutect2, varscan2
- DCHS2 | n.7436T>C | RNA (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100602140; called by muse, mutect2
- DCHS2 | n.1301C>G | RNA (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100252432; called by muse, mutect2, varscan2
- MASP1 | c.1303+5417G>T | Intron (SNP) | VAF 20/133 reads (15%) | catalogued as COSV99962582; called by muse, mutect2, varscan2
- SNORD115-43 | n.26G>A | RNA (SNP) | VAF 42/248 reads (17%) | called by muse, mutect2, varscan2
